Somatic mutation profile of tumor specimen MMRF_1033_1_BM_CD138pos (aliquot MMRF_1033_1_BM_CD138pos_T2_TSE61_K02461) from MMRF case MMRF_1033, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.9 years (23,692 days).
Specimen MMRF_1033_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ac5c5eb-0655-4169-9402-4bda98615cff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1033_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1033_1_PB_Whole_C1_TSE61_K02454; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80f9cb8f-a7bd-41c9-8d53-eee66b8da2b5

The open-access MAF lists 61 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, 3'UTR 20, Silent 7, RNA 2, Frame Shift Del 2, Intron 2, 5'Flank 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM29 | c.2122C>A p.Q708K | Missense Mutation (SNP) | VAF 112/265 reads (42%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV63667872; called by muse, mutect2, varscan2
- CLSTN2 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.805); catalogued as rs1047973426; called by muse, mutect2, varscan2
- FNDC1 | c.4475G>A p.R1492Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.01); catalogued as rs1478826148, COSV51936330; called by muse, mutect2, varscan2
- JAG1 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs564566567, COSV54757001; called by muse, mutect2, varscan2
- KIAA1671 | c.5117C>T p.T1706M | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs150764825; called by muse, mutect2
- NAV2 | c.2242C>T p.R748W (on ENST00000396087 / NM_001244963.2; = p.R725W on NM_145117.5) | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149432799; called by muse, mutect2, varscan2
- RNF10 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1321194429; called by muse, mutect2, varscan2
- SETDB1 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs746384059, COSV54980157; called by muse, mutect2, varscan2
- SGTA | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as rs1250621953; called by muse, mutect2, varscan2
- TRARG1 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100416787; called by muse, mutect2, varscan2
- USH2A | c.6974T>C p.L2325P | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as rs907905266, COSV100240298; called by muse, mutect2, varscan2
- DDX5 | c.1733del p.G578Efs*11 | Frame Shift Del (DEL) | VAF 32/97 reads (33%) | called by mutect2, pindel, varscan2
- DGKB | c.1328T>C p.V443A | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ETS2 | c.940T>G p.F314V | Missense Mutation (SNP) | VAF 68/105 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FYB2 | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- HERC2 | c.11320G>A p.A3774T | Missense Mutation (SNP) | VAF 121/202 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- KMT2B | c.5968G>A p.D1990N | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- NDUFA10 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.32); called by muse, mutect2
- NEURL1B | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NR2F2 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- PCDHB13 | c.374T>G p.I125R | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASA2 | c.797_801del p.D266Vfs*4 | Frame Shift Del (DEL) | VAF 31/128 reads (24%) | called by mutect2, pindel, varscan2
- RASA2 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNCAIP | c.1632A>C p.Q544H | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- TF | c.1333T>G p.Y445D | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USP44 | c.636G>T p.K212N | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- WDSUB1 | c.598C>A p.L200I | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BRD2 | c.255A>G p.V85= | Silent (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- COL11A1 | c.51C>T p.F17= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV100617011; called by muse, mutect2, varscan2
- DCHS1 | c.6693C>G p.T2231= | Silent (SNP) | VAF 42/140 reads (30%) | called by muse, mutect2, varscan2
- HDLBP | c.2226C>G p.L742= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV100190287; called by muse, varscan2
- MAPKBP1 | c.507T>C p.I169= | Silent (SNP) | VAF 75/131 reads (57%) | called by muse, mutect2, varscan2
- PLA2G4D | c.525T>A p.A175= | Silent (SNP) | VAF 22/103 reads (21%) | called by muse, mutect2, varscan2
- VSX1 | c.732C>T p.H244= | Silent (SNP) | VAF 50/112 reads (45%) | called by muse, mutect2, varscan2
- ANK2 | c.*364A>G | 3'UTR (SNP) | VAF 46/115 reads (40%) | catalogued as rs1352272383; called by muse, mutect2, varscan2
- B3GNT2 | c.*1232A>G | 3'UTR (SNP) | VAF 17/49 reads (35%) | catalogued as rs1303118217; called by muse, mutect2, varscan2
- CRABP1 | c.*109T>A | 3'UTR (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- DCAF12 | c.*517A>G | 3'UTR (SNP) | VAF 87/138 reads (63%) | called by muse, mutect2, varscan2
- DDX25 | c.*41G>A | 3'UTR (SNP) | VAF 51/146 reads (35%) | called by muse, mutect2, varscan2
- EFNA5 | c.*929C>T | 3'UTR (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- ELP3 | c.*775A>T | 3'UTR (SNP) | VAF 39/81 reads (48%) | called by muse, mutect2, varscan2
- ERBB4 | c.*5739A>G | 3'UTR (SNP) | VAF 57/126 reads (45%) | called by muse, mutect2, varscan2
- FAM86EP | n.615A>G | RNA (SNP) | VAF 85/193 reads (44%) | called by muse, mutect2, varscan2
- FBLIM1 | c.*1094A>G | 3'UTR (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2
- FLT1 | c.*2403C>T | 3'UTR (SNP) | VAF 61/141 reads (43%) | catalogued as rs571122200; called by muse, mutect2, varscan2
- KC6 | n.313+147C>T | Intron (SNP) | VAF 12/109 reads (11%) | catalogued as rs1247095273; called by muse, mutect2, varscan2
- KDSR | c.*2681T>A | 3'UTR (SNP) | VAF 32/102 reads (31%) | called by muse, mutect2, varscan2
- KDSR | c.*2680C>T | 3'UTR (SNP) | VAF 33/103 reads (32%) | called by muse, mutect2, varscan2
- KIR2DL4 | c.*375C>A | 3'UTR (SNP) | VAF 25/70 reads (36%) | called by muse, mutect2, varscan2
- LRATD1 | c.*413G>T | 3'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- MEF2A | c.*3632C>T | 3'UTR (SNP) | VAF 35/57 reads (61%) | catalogued as rs1168529714; called by muse, mutect2, varscan2
- MGC27382 | n.1165A>G | RNA (SNP) | VAF 26/66 reads (39%) | catalogued as rs534599107; called by muse, mutect2, varscan2
- MIER1 | c.*1944_*1947del | 3'UTR (DEL) | VAF 63/140 reads (45%) | called by mutect2, pindel, varscan2
- NCAPD3 | chr11:134224461 G>A | 5'Flank (SNP) | VAF 25/74 reads (34%) | catalogued as rs974982820; called by muse, mutect2, varscan2
- PCDHA9 | c.2394+2282G>A | Intron (SNP) | VAF 10/48 reads (21%) | catalogued as rs896732448, COSV56536242; called by muse, mutect2, varscan2
- POU5F1 | chr6:31173856 G>T | 5'Flank (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- RNF212 | c.-35G>A | 5'UTR (SNP) | VAF 10/22 reads (45%) | catalogued as rs770989872; called by muse, mutect2
- SCN2A | c.*920G>C | 3'UTR (SNP) | VAF 49/115 reads (43%) | called by muse, mutect2, varscan2
- SERINC1 | c.*357T>C | 3'UTR (SNP) | VAF 71/160 reads (44%) | called by muse, mutect2, varscan2
- SLC1A2 | c.*572A>T | 3'UTR (SNP) | VAF 74/251 reads (29%) | called by muse, mutect2, varscan2
- ZADH2 | c.*3919_*3921del | 3'UTR (DEL) | VAF 105/237 reads (44%) | called by mutect2, pindel, varscan2
